Somatic mutation profile of tumor specimen TCGA-DS-A1OA-01A (aliquot TCGA-DS-A1OA-01A-11D-A16Y-08) from TCGA case TCGA-DS-A1OA, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 77.1 years (28,160 days).
Specimen TCGA-DS-A1OA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 81284107-6987-46bf-995e-450b353f62c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DS-A1OA-10A (Blood Derived Normal), aliquot TCGA-DS-A1OA-10A-01D-A16Y-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c5dad66-f50f-47c0-81c7-cb9de6e1bfdf

The open-access MAF lists 51 somatic variants for this specimen: 33 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 16, RNA 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>G p.R505G (on ENST00000281708 / NM_001349798.2; = p.R425G on NM_018315.5) | Missense Mutation (SNP) | VAF 59/139 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADCY6 | c.2909T>C p.L970P | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57169396; called by muse, mutect2, varscan2
- C7 | c.1846G>A p.D616N | Missense Mutation (SNP) | VAF 75/109 reads (69%) | SIFT tolerated (0.56); PolyPhen benign (0.028); catalogued as COSV57473496, COSV57477539; called by muse, mutect2, varscan2
- CACNA2D4 | c.898G>A p.G300S | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs753108402, COSV54955340, COSV99765358; called by muse, mutect2, varscan2
- CDKN1A | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs779717089, COSV55187110, COSV55190712; called by muse, mutect2, varscan2
- CELSR2 | c.1162T>C p.S388P | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.544); catalogued as COSV54776203; called by muse, mutect2, varscan2
- COL4A5 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as rs763366059, COSV60360945; called by muse, mutect2, varscan2
- ERVW-1 | c.564A>G p.I188M | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs796542781; called by mutect2, varscan2
- FCRL3 | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.77); PolyPhen benign (0.012); catalogued as COSV63843534; called by muse, mutect2, varscan2
- GP6 | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1329871271, COSV100117418, COSV59977425; called by muse, mutect2, varscan2
- GRIA4 | c.2203G>C p.E735Q | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV56909323; called by muse, mutect2, varscan2
- KRT15 | c.631G>T p.G211C | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753633915, COSV54178243, COSV54180880; called by muse, mutect2, varscan2
- NUP155 | c.1097T>C p.V366A (on ENST00000231498 / NM_153485.3; = p.V307A on NM_004298.4) | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV51532573; called by muse, mutect2, varscan2
- P3H2 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as rs376765314; ClinVar: uncertain significance; called by muse, mutect2
- PCDH19 | c.466C>G p.P156A | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55258928; called by muse, mutect2, varscan2
- PGM2 | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV67939277; called by muse, mutect2, varscan2
- PHACTR4 | c.535C>T p.H179Y (on ENST00000373839 / NM_001350159.2; = p.H189Y on NM_023923.4) | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs1389171456, COSV100868410; called by muse, mutect2, varscan2
- PNLIP | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs781245524, COSV65041366; called by muse, mutect2, varscan2
- PSME3 | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.965); catalogued as rs751193290, COSV53198717; called by muse, mutect2, varscan2
- SERPINA3 | c.868A>C p.M290L | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs767884919, COSV67586695; called by muse, varscan2
- SMARCAD1 | c.205C>G p.P69A | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.986); catalogued as rs555203609, COSV62775498; called by muse, mutect2, varscan2
- SPOPL | c.1085C>G p.S362C | Missense Mutation (SNP) | VAF 119/199 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV54514917; called by muse, mutect2, varscan2
- TAS2R19 | c.514A>G p.I172V | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.99); PolyPhen benign (0.01); catalogued as rs1463872508, COSV66828778; called by muse, mutect2, varscan2
- TLR4 | c.1057C>T p.L353F (on ENST00000355622 / NM_138554.5; = p.L313F on NM_003266.4) | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs148638298, COSV62922808; called by muse, mutect2
- TMEM130 | c.748C>A p.P250T | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); catalogued as COSV59559911, COSV59560202; called by muse, mutect2, varscan2
- TP63 | c.563A>T p.K188M | Missense Mutation (SNP) | VAF 97/152 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53199618, COSV53214070; called by muse, mutect2, varscan2
- TRUB2 | c.721G>C p.E241Q | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV65760026; called by muse, mutect2, varscan2
- TTN | c.62879C>T p.S20960L (on ENST00000591111; = p.S13536L on NM_003319.4) | Missense Mutation (SNP) | VAF 43/208 reads (21%) | PolyPhen benign (0.073); catalogued as COSV60208249; called by muse, mutect2, varscan2
- TTN | c.8903C>T p.P2968L (on ENST00000591111; = p.P2922L on NM_003319.4) | Missense Mutation (SNP) | VAF 14/22 reads (64%) | PolyPhen probably damaging (0.999); catalogued as COSV60208295; called by muse, mutect2, varscan2
- UNC5CL | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0.003); catalogued as rs1005099050, COSV55111038; called by muse, mutect2
- ZBED4 | c.1154C>T p.S385L | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.72); PolyPhen benign (0.019); catalogued as rs780126311, COSV53466947; called by muse, mutect2, varscan2
- ZNF217 | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 67/182 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767530299, COSV56598338; called by muse, mutect2, varscan2
- CLUH | c.3178_3195+1del p.X1060_splice (on ENST00000435359; = p.X1099_splice on NM_015229.4 and 1 other RefSeq transcript) | Splice Site (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- BCL11B | c.2634C>T p.G878= (on ENST00000357195 / NM_001282237.2; = p.G807= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV61732882; called by muse, mutect2, varscan2
- BCL3 | c.1332G>A p.P444= | Silent (SNP) | VAF 111/175 reads (63%) | catalogued as rs773229337, COSV51234604, COSV51234748; called by muse, varscan2
- CHST4 | c.1053C>T p.G351= | Silent (SNP) | VAF 25/41 reads (61%) | catalogued as rs1209201255, COSV58297815; called by muse, mutect2, varscan2
- CLDN3 | c.597C>T p.S199= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as rs901356754, COSV67777262; called by muse, mutect2, varscan2
- CYP1A2 | c.924C>T p.V308= | Silent (SNP) | VAF 66/134 reads (49%) | catalogued as COSV59660371; called by muse, mutect2, varscan2
- DDI2 | c.1140C>T p.D380= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV60780550; called by muse, mutect2, varscan2
- FBXL5 | c.1518A>G p.V506= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV100377709; called by muse, mutect2, varscan2
- LYST | c.2724C>T p.C908= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as rs201440611, COSV67705652; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- MICU1 | c.1284G>A p.L428= (on ENST00000361114 / NM_001195518.2; = p.L434= on NM_006077.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV63146311; called by mutect2, varscan2
- NSUN6 | c.126G>A p.L42= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs762353306, COSV66033035, COSV66034309; called by muse, mutect2, varscan2
- OPRM1 | c.252G>T p.G84= | Silent (SNP) | VAF 44/62 reads (71%) | catalogued as COSV57681265; called by muse, mutect2, varscan2
- OSBPL6 | c.2112G>A p.S704= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs201982642; called by muse, mutect2, varscan2
- PLCD3 | c.1455C>T p.P485= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs146128980, COSV100504229; called by muse, varscan2
- PODXL2 | c.306G>A p.E102= | Silent (SNP) | VAF 29/101 reads (29%) | catalogued as COSV61066047; called by muse, mutect2, varscan2
- THSD4 | c.2397C>T p.L799= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV55977508; called by muse, mutect2, varscan2
- ZNF613 | c.75C>T p.L25= | Silent (SNP) | VAF 39/110 reads (35%) | catalogued as rs777305978, COSV53273062; called by muse, mutect2, varscan2
- PCDHA3 | c.2394+44C>G | Intron (SNP) | VAF 6/20 reads (30%) | catalogued as COSV63539279, COSV63544149; called by muse, mutect2, varscan2
- TMEM183B | n.1078G>A | RNA (SNP) | VAF 38/257 reads (15%) | catalogued as rs200889994; called by muse, mutect2, varscan2
